Somatic mutation profile of tumor specimen C3L-04080-02 (aliquot CPT0221470008) from CPTAC case C3L-04080, project CPTAC-3 (Pancreas — Ductal and Lobular Neoplasms). Sex at birth: male; Vital status: Dead; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Pancreas, NOS; AJCC pathologic stage: Stage IIB; Tumor grade: G3; Age at diagnosis: 70.8 years (25,862 days).
Specimen C3L-04080-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Pancreas; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 72dd6633-3504-48f8-b8ae-0c4290e68c76.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-04080-31 (Blood Derived Normal), aliquot CPT0220550002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/35c20a14-bc9a-4bf1-acff-d7e9bc12f046

The open-access MAF lists 42 somatic variants for this specimen: 28 protein-altering or splice-affecting, 7 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 24, Silent 7, 5'UTR 3, Intron 3, Nonsense Mutation 2, 3'Flank 1, Frame Shift Del 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.34G>C p.G12R | Missense Mutation (SNP) | VAF 71/513 reads (14%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen possibly damaging (0.497); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.673-9_673del p.X225_splice | Splice Site (DEL) | VAF 57/490 reads (12%) | hotspot (GDC flag); called by mutect2, pindel, varscan2
- CA10 | c.122G>T p.G41V | Missense Mutation (SNP) | VAF 83/435 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV53360365; called by muse, varscan2
- CELSR1 | c.4006G>A p.V1336M | Missense Mutation (SNP) | VAF 8/166 reads (5%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.947); catalogued as COSV53083748; called by muse, mutect2
- DTX3 | c.607G>A p.G203S | Missense Mutation (SNP) | VAF 57/466 reads (12%) | SIFT tolerated (0.11); PolyPhen benign (0.094); catalogued as rs1308727968; called by muse, mutect2, varscan2
- LCP1 | c.145A>G p.R49G | Missense Mutation (SNP) | VAF 83/490 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.14); catalogued as COSV59939986; called by muse, mutect2, varscan2
- OR6B3 | c.692C>T p.A231V | Missense Mutation (SNP) | VAF 20/480 reads (4%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.616); catalogued as COSV100097177; called by muse, mutect2
- PARP4 | c.3080T>G p.F1027C | Missense Mutation (SNP) | VAF 42/220 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV67960505; called by muse, mutect2, varscan2
- PKD1L1 | c.970A>T p.M324L | Missense Mutation (SNP) | VAF 66/475 reads (14%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as rs944419000, COSV99220998; called by muse, mutect2, varscan2
- SLC25A51 | c.233G>A p.R78Q | Missense Mutation (SNP) | VAF 34/374 reads (9%) | SIFT tolerated (0.19); PolyPhen benign (0.124); catalogued as rs769274693, COSV54252107; called by muse, mutect2
- SMAD4 | c.170T>C p.L57S | Missense Mutation (SNP) | VAF 44/252 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV61684770, COSV61693463; called by muse, mutect2, varscan2
- SPATA31D4 | c.2524C>T p.R842* | Nonsense Mutation (SNP) | VAF 67/787 reads (9%) | catalogued as rs759647627; called by muse, varscan2
- STAM2 | c.33A>C p.Q11H | Missense Mutation (SNP) | VAF 64/608 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.005); catalogued as COSV55731296; called by muse, mutect2
- TAF1D | c.166C>T p.P56S | Missense Mutation (SNP) | VAF 23/185 reads (12%) | SIFT tolerated (0.18); PolyPhen benign (0.029); catalogued as rs764603250; called by muse, mutect2, varscan2
- TRIM51GP | c.410G>A p.R137Q | Missense Mutation (SNP) | VAF 80/508 reads (16%) | SIFT tolerated (0.11); PolyPhen benign (0.341); catalogued as rs755102928; called by muse, mutect2, varscan2
- ARHGAP4 | c.727C>T p.R243C | Missense Mutation (SNP) | VAF 81/319 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); called by muse, mutect2, varscan2
- C9orf43 | c.776T>A p.M259K | Missense Mutation (SNP) | VAF 49/200 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- CENPJ | c.3438C>A p.D1146E | Missense Mutation (SNP) | VAF 76/583 reads (13%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- DPP10 | c.2073C>A p.Y691* | Nonsense Mutation (SNP) | VAF 77/260 reads (30%) | called by muse, mutect2, varscan2
- FOXK1 | c.1956del p.A653Rfs*62 | Frame Shift Del (DEL) | VAF 40/362 reads (11%) | called by mutect2, varscan2
- MRPS28 | c.208C>A p.Q70K | Missense Mutation (SNP) | VAF 28/287 reads (10%) | SIFT tolerated (0.95); PolyPhen benign (0.007); called by muse, mutect2
- MUC5AC | c.14803A>G p.T4935A | Missense Mutation (SNP) | VAF 91/485 reads (19%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.962); called by muse, mutect2, varscan2
- NUDCD1 | c.1289C>T p.T430I | Missense Mutation (SNP) | VAF 33/116 reads (28%) | SIFT tolerated (0.56); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- RIC8A | c.313G>A p.V105I | Missense Mutation (SNP) | VAF 62/410 reads (15%) | SIFT tolerated (0.27); PolyPhen benign (0); called by muse, mutect2, varscan2
- THSD7B | c.44G>A p.R15K | Missense Mutation (SNP) | VAF 43/188 reads (23%) | SIFT tolerated (0.24); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- UPK3B | c.202A>T p.T68S | Missense Mutation (SNP) | VAF 22/231 reads (10%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.024); called by muse, mutect2
- YTHDC2 | c.1365A>T p.E455D | Missense Mutation (SNP) | VAF 35/237 reads (15%) | SIFT tolerated (0.12); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- ZFR | c.85T>G p.F29V | Missense Mutation (SNP) | VAF 64/465 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- AC006059.2 | c.447C>T p.A149= | Silent (SNP) | VAF 40/255 reads (16%) | catalogued as rs141032680; called by muse, mutect2, varscan2
- COLEC12 | c.42C>T p.F14= | Silent (SNP) | VAF 64/590 reads (11%) | catalogued as rs778096255, COSV68375160; called by muse, mutect2, varscan2
- EBF3 | c.1518G>A p.S506= (on ENST00000355311 / NM_001375392.1; = p.S497= on NM_001005463.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 37/194 reads (19%) | catalogued as rs372476626; called by muse, mutect2, varscan2
- EIPR1 | c.744A>G p.G248= | Silent (SNP) | VAF 88/459 reads (19%) | called by muse, mutect2, varscan2
- EXTL1 | c.618G>A p.P206= | Silent (SNP) | VAF 26/109 reads (24%) | catalogued as rs768099208, COSV65338459; called by muse, mutect2, varscan2
- IFT52 | c.216C>T p.I72= | Silent (SNP) | VAF 36/300 reads (12%) | called by muse, mutect2, varscan2
- PRUNE2 | c.2295T>C p.F765= | Silent (SNP) | VAF 16/510 reads (3%) | called by muse, mutect2
- BLOC1S5-TXNDC5 | c.372+39125G>T | Intron (SNP) | VAF 58/503 reads (12%) | called by muse, mutect2, varscan2
- DYRK2 | c.198+1588A>C | Intron (SNP) | VAF 45/280 reads (16%) | called by muse, mutect2, varscan2
- GYPB | c.-8A>T | 5'UTR (SNP) | VAF 39/300 reads (13%) | catalogued as rs772536215; called by muse, mutect2, varscan2
- MOB3C | c.-35del | 5'UTR (DEL) | VAF 20/119 reads (17%) | catalogued as COSV54718182; called by mutect2, pindel
- PGAM5P1 | chr5:109884463 G>A | 3'Flank (SNP) | VAF 72/482 reads (15%) | catalogued as rs187671836; called by muse, mutect2, varscan2
- RGL3 | c.-8C>A | 5'UTR (SNP) | VAF 49/272 reads (18%) | catalogued as rs1403034359, COSV62698221; called by muse, mutect2, varscan2
- RIMS2 | c.698+52954A>G | Intron (SNP) | VAF 38/406 reads (9%) | catalogued as rs572378309, COSV51655429; called by mutect2, varscan2
